Somatic mutation profile of tumor specimen BA2477D (aliquot aq-BA2477D) from BEATAML1.0 case 2219, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,626 days).
Specimen BA2477D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fe30742-ad02-4663-a28b-96473859e7ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3000D (Solid Tissue Normal), aliquot aq-BA3000D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64c87ab1-2161-4fa0-ba12-f327378fbcf9

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNND1 | c.2083C>A p.R695S (on ENST00000399050 / NM_001085458.2; = p.R689S on NM_001331.3) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV62382394; called by muse, mutect2
- FGD3 | c.381C>A p.D127E | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV61597208; called by muse, mutect2
- IQSEC3 | c.1805C>A p.T602K (on ENST00000538872 / NM_001170738.2; = p.T299K on NM_015232.1) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs1555088225; called by muse, mutect2
- N4BP2L2 | c.1889G>T p.R630I (on ENST00000674422; = p.R201I on NM_033111.4) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- PDGFRB | c.1562T>C p.V521A | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- TENM4 | c.5823G>T p.R1941S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.115); called by muse, mutect2
